Somatic mutation profile of tumor specimen TARGET-20-PANLIZ-04A (aliquot TARGET-20-PANLIZ-04A-01D) from TARGET case TARGET-20-PANLIZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,102 days).
Specimen TARGET-20-PANLIZ-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a0eb32a-f2c3-46a7-926c-448a6026c486.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANLIZ-14A (Bone Marrow Normal), aliquot TARGET-20-PANLIZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7df0dae5-9ffc-423f-b7f8-d45bf67d5f51

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Splice Region 1, In Frame Del 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND2 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs587777618, CM144533, COSV54222671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- EFEMP1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.486); catalogued as rs142542256; called by muse, mutect2, varscan2
- ELAVL1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV60966251; called by muse, mutect2, varscan2
- EZH2 | c.2211_2212insAATCCCCTC p.V737_G738insNPL (on ENST00000460911 / NM_001203247.2; = p.V742_G743insNPL on NM_004456.5) | In Frame Ins (INS) | VAF 28/114 reads (25%) | catalogued as COSV57461298, COSV57462628; called by mutect2, pindel, varscan2
- FAM135B | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs750908660, COSV52703573, COSV52705631; called by muse, mutect2, varscan2
- FLG | c.6509A>C p.H2170P | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV64242501; called by muse, mutect2, varscan2
- H2BC3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.108); catalogued as COSV63550866; called by muse, mutect2, varscan2
- MMP14 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446692471, COSV100314304; called by muse, mutect2
- NOTCH2 | c.5657G>A p.R1886H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458372923, COSV56684256; called by muse, mutect2, varscan2
- NUGGC | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374912166; called by muse, mutect2, varscan2
- ORM1 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs554585948, COSV52279401; called by muse, mutect2, varscan2
- SMAD4 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61691611; called by muse, mutect2
- SRCAP | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52670805; called by muse, mutect2, varscan2
- TRH | c.355C>G p.R119G | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as CM142647, COSV57014834; called by muse, mutect2, varscan2
- TUT4 | c.4913C>A p.P1638Q | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV57112607; called by muse, mutect2, varscan2
- VIM | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs372258946; called by muse, mutect2, varscan2
- ZNF510 | c.1217G>C p.C406S | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV56296934; called by muse, mutect2, varscan2
- DHX15 | c.2228_2230del p.T743del | In Frame Del (DEL) | VAF 76/280 reads (27%) | called by pindel, varscan2
- SLC1A5 | c.1028dup p.L344Afs*25 | Frame Shift Ins (INS) | VAF 46/136 reads (34%) | called by mutect2, pindel, varscan2
- SLC44A3 | c.1074A>C p.G358= (on ENST00000271227 / NM_001114106.3; = p.G310= on NM_152369.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- DAPK1 | c.3444C>T p.V1148= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs748723486, COSV63786646, COSV63791547; called by muse, mutect2, varscan2
- IL3 | c.393G>A p.T131= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as rs750120195, COSV57308338; called by muse, mutect2, varscan2
- KCNIP3 | c.636G>A p.A212= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs763753766, COSV54665758; called by muse, mutect2, varscan2
- NR1H4 | c.219G>A p.S73= (on ENST00000551379 / NM_001206993.2; = p.S63= on NM_005123.4) | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as rs772649147, COSV99501379; called by muse, mutect2, varscan2
- RPTOR | c.1230C>G p.A410= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs375864642, COSV60807121; called by muse, mutect2, varscan2
- SMARCA2 | c.3810G>A p.R1270= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV61806506; called by muse, mutect2, varscan2
- TRIM62 | c.462C>T p.T154= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs546251491, COSV52220138, COSV52221074; called by muse, mutect2, varscan2
